Somatic mutation profile of tumor specimen MMRF_2765_1_BM_CD138pos (aliquot MMRF_2765_1_BM_CD138pos_T1_KHS5U_L15717) from MMRF case MMRF_2765, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2765_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a7e8bb0-f44b-4df8-bdae-ec6d12b2e0f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2765_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2765_1_PB_WBC_C2_KHS5U_L15761; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/345cff1c-5b29-41a3-a320-dce7243ce32f

The open-access MAF lists 138 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 49, Intron 13, Silent 11, 5'UTR 5, Frame Shift Del 2, RNA 2, 5'Flank 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKBKB | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1563340753, COSV60596575; ClinVar: pathogenic; called by muse, mutect2
- ADRA1D | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs923834810, COSV101063122; called by muse, mutect2, varscan2
- ATP5F1D | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1238350460; called by muse, mutect2, varscan2
- C19orf18 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs75553659, COSV58708212; called by muse, mutect2, varscan2
- DKK2 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs267599976, COSV53403075, COSV99569303; called by muse, mutect2, varscan2
- EN2 | c.852C>G p.N284K | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs560776197; called by muse, mutect2
- FGA | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762511080, COSV57399681; called by muse, mutect2, varscan2
- FLNC | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV57966579; called by muse, mutect2, varscan2
- FOXF1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1369235355, COSV99296667; called by muse, mutect2, varscan2
- ISYNA1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1290686695; called by muse, mutect2, varscan2
- JAKMIP1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51528285; called by muse, mutect2, varscan2
- LRRTM1 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54441908; called by muse, mutect2, varscan2
- NWD1 | c.4077C>A p.D1359E | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751633850; called by muse, mutect2, varscan2
- PRM3 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as rs1352744857, COSV54113177, COSV99617748; called by muse, mutect2, varscan2
- ROS1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs753367775; called by muse, varscan2
- SPOCK3 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314961619; called by muse, mutect2, varscan2
- TBC1D32 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.175); catalogued as COSV51536068; called by muse, mutect2
- TENT5C | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769480797, COSV65616467, COSV65616574; called by muse, mutect2
- VTCN1 | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as rs576065477; called by muse, mutect2, varscan2
- ZBED9 | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs572680396, COSV71729149, COSV71729398; called by muse, mutect2, varscan2
- ZFHX4 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50508042; called by muse, mutect2, varscan2
- ZNF780B | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs866042253, COSV99665267; called by muse, mutect2, varscan2
- AGBL5 | c.1577del p.N526Tfs*69 | Frame Shift Del (DEL) | VAF 36/174 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.193); called by muse, mutect2
- CBLB | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD47 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CR1L | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 104/373 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CRYBB2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.8234G>C p.W2745S | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIPK1C | c.322T>A p.W108R | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DMTF1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 107/425 reads (25%) | called by muse, mutect2, varscan2
- DMXL2 | c.8827T>C p.S2943P | Missense Mutation (SNP) | VAF 82/459 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- EEF1D | c.814_815del p.S272Cfs*27 | Frame Shift Del (DEL) | VAF 98/324 reads (30%) | called by pindel, varscan2
- GIMAP5 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- HEG1 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCP | c.2915C>A p.A972E (on ENST00000620378; = p.A1032E on NM_001366122.1) | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.988); called by muse, mutect2
- KIAA1549L | c.4951G>T p.V1651F (on ENST00000321505; = p.V1948F on NM_012194.3) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LIMCH1 | c.1811A>T p.E604V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MAMLD1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP4K3 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MGAT5 | c.557T>G p.F186C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MMP10 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- OGFRL1 | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5AR1 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PRSS53 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- RASEF | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFR1 | c.137C>A p.P46H (on ENST00000369727 / NM_001002759.1; = p.P33H on NM_145247.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC6A16 | c.1909C>A p.P637T | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPACA1 | c.157A>C p.N53H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.466); called by muse, varscan2
- TAF2 | c.1112A>T p.K371M | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); called by muse, mutect2
- THBD | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF215 | c.1101T>G p.I367M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF367 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF429 | c.1587A>T p.K529N | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF514 | c.1198dup p.L400Pfs*136 | Frame Shift Ins (INS) | VAF 152/395 reads (38%) | called by mutect2, pindel, varscan2
- AUTS2 | c.2781C>T p.R927= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs1366624824; called by muse, mutect2, varscan2
- CADM2 | c.717A>G p.Q239= (on ENST00000407528 / NM_001167674.2; = p.Q241= on NM_153184.4) | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CD5 | c.1338C>T p.A446= | Silent (SNP) | VAF 60/237 reads (25%) | called by muse, mutect2, varscan2
- CDC14B | c.87G>A p.K29= | Silent (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- CEP290 | c.5892A>G p.L1964= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- NFATC1 | c.2205G>A p.A735= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs368426396; called by muse, mutect2, varscan2
- PCDHGA3 | c.1290G>A p.P430= | Silent (SNP) | VAF 58/259 reads (22%) | catalogued as COSV53930432; called by muse, mutect2, varscan2
- PHKA2 | c.2313G>T p.S771= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- SH3RF3 | c.1734C>T p.H578= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs754398613, COSV100513016; called by muse, mutect2, varscan2
- TMEM255B | c.444C>T p.D148= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as rs201537526; called by muse, mutect2, varscan2
- ZNF606 | c.2142G>A p.G714= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- AC012236.1 | n.455-45G>A | Intron (SNP) | VAF 51/228 reads (22%) | catalogued as rs773230625; called by muse, mutect2, varscan2
- AMOTL1 | c.*5622G>A | 3'UTR (SNP) | VAF 45/130 reads (35%) | catalogued as rs560358991; called by muse, varscan2
- AR | c.*4931A>G | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-116G>A | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as rs959145960; called by muse, mutect2
- BCL11A | c.*663_*665del | 3'UTR (DEL) | VAF 28/136 reads (21%) | catalogued as rs1252080301; called by pindel, varscan2
- BLOC1S5-TXNDC5 | c.372+39518T>G | Intron (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- BNIP3P1 | n.330C>T | RNA (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- CAAP1 | c.*1593G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CACNA1B | c.*1915C>G | 3'UTR (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- CACNG8 | c.*2427G>A | 3'UTR (SNP) | VAF 45/183 reads (25%) | catalogued as rs907708676; called by muse, mutect2, varscan2
- CAMK2D | chr4:113761245 A>G | 5'Flank (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- CCNC | c.*717dup | 3'UTR (INS) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- CDH11 | c.*435C>T | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- CYTL1 | c.*423T>A | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- DLGAP3 | c.*35G>A | 3'UTR (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- ERG28 | c.*106T>G | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- ESAM | c.250-64G>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ETV5 | c.*1825A>T | 3'UTR (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- FBXL17 | c.*551_*571del | 3'UTR (DEL) | VAF 30/156 reads (19%) | called by mutect2, pindel, varscan2
- FCHSD1 | c.*124C>G | 3'UTR (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- FGF13 | c.*346G>A | 3'UTR (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- FOXK1 | c.*6120T>C | 3'UTR (SNP) | VAF 99/163 reads (61%) | called by muse, mutect2, varscan2
- GALNTL6 | c.138+275G>A | Intron (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- GLIS3 | c.*1702C>A | 3'UTR (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- GOLPH3L | c.*1722T>A | 3'UTR (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- GPSM1 | chr9:136326909 A>T | 5'Flank (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- HGF | c.*1412T>G | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- HNRNPCP2 | n.376T>A | RNA (SNP) | VAF 89/232 reads (38%) | called by muse, mutect2, varscan2
- HSPA12A | c.1287-88G>A | Intron (SNP) | VAF 15/56 reads (27%) | catalogued as COSV65023001; called by muse, mutect2, varscan2
- IGF2BP1 | c.*4373G>T | 3'UTR (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- IKZF1 | c.*759C>T | 3'UTR (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
- KBTBD11 | c.*3480G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- KCTD19 | c.301-928T>C | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs957426431; called by mutect2, varscan2
- KCTD20 | c.-34A>C | 5'UTR (SNP) | VAF 118/454 reads (26%) | called by muse, mutect2, varscan2
- KLHDC7A | c.*1732G>T | 3'UTR (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
- LAPTM4B | chr8:97853043 ins T | 3'Flank (INS) | VAF 26/130 reads (20%) | called by mutect2, pindel, varscan2
- LCE2B | c.*131G>T | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- LDHAL6A | c.418+3027T>C | Intron (SNP) | VAF 18/78 reads (23%) | catalogued as rs1036819269; called by muse, mutect2, varscan2
- LINC00632 | n.104+1898C>T | Intron (SNP) | VAF 115/201 reads (57%) | called by muse, mutect2, varscan2
- LMLN | c.*1006dup | 3'UTR (INS) | VAF 17/54 reads (31%) | called by mutect2, varscan2
- LPCAT4 | c.712-30C>T | Intron (SNP) | VAF 48/235 reads (20%) | catalogued as rs537015655; called by muse, mutect2, varscan2
- LRP4 | c.*997T>C | 3'UTR (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- MAFB | c.-181G>A | 5'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- MAMLD1 | c.*1010T>A | 3'UTR (SNP) | VAF 72/123 reads (59%) | called by muse, mutect2, varscan2
- MBNL2 | c.*284A>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs1308133804; called by muse, mutect2, varscan2
- MEF2C | c.-119G>A | 5'UTR (SNP) | VAF 184/388 reads (47%) | called by muse, mutect2, varscan2
- MEF2C | c.-120G>A | 5'UTR (SNP) | VAF 182/386 reads (47%) | called by muse, mutect2, varscan2
- MEX3C | c.*1071C>T | 3'UTR (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- MIB1 | c.*5360G>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- NBPF3 | c.*323T>G | 3'UTR (SNP) | VAF 3/18 reads (17%) | catalogued as rs200265424; called by muse, mutect2
- NELL1 | c.*21C>T | 3'UTR (SNP) | VAF 86/425 reads (20%) | catalogued as rs368471379, COSV100125612; called by muse, mutect2, varscan2
- NTPCR | c.*612A>G | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- PAX7 | c.*789C>A | 3'UTR (SNP) | VAF 48/115 reads (42%) | catalogued as rs186572332; called by muse, mutect2, varscan2
- PCSK9 | c.524-32C>T | Intron (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- PHF21B | c.*1176G>A | 3'UTR (SNP) | VAF 94/284 reads (33%) | catalogued as rs904174055; called by muse, mutect2, varscan2
- PMP2 | c.*349G>T | 3'UTR (SNP) | VAF 40/118 reads (34%) | called by muse, mutect2, varscan2
- POGK | c.*1748G>C | 3'UTR (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- POGZ | c.*1417G>A | 3'UTR (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- RNF125 | c.*3061T>G | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- RSBN1 | c.*2026A>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as rs943627236, COSV99792880; called by muse, varscan2
- SIX6 | c.*1439G>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- SMAD2 | c.*35T>C | 3'UTR (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- SPACA6 | c.-50G>T | 5'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- SRP19 | c.*2187C>T | 3'UTR (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- THSD7A | c.*788G>A | 3'UTR (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- TTC28 | c.*3557C>T | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- UBE2H | c.*1939A>G | 3'UTR (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- VPS35 | c.*481C>G | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- WDR19 | c.1479+726T>G | Intron (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- XKR4 | c.806+61070G>T | Intron (SNP) | VAF 101/281 reads (36%) | called by muse, mutect2, varscan2
- XXYLT1 | c.*559G>A | 3'UTR (SNP) | VAF 39/106 reads (37%) | catalogued as rs112192375; called by muse, mutect2, varscan2
- ZNF493 | c.*728G>T | 3'UTR (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
